Somatic mutation profile of tumor specimen 0DAEHQ from CCDI case PBBIXX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, benign; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.8 years (6,882 days).
Specimen 0DAEHQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7a7fd10-d2a0-4ad7-91f3-e13d6f15cd20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAEHC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a8af8d9-0343-489b-895c-00a1c8467465

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 170/712 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DYSF | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 115/571 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770593405, COSV50557235, COSV99250062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC2A12 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 173/708 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs750692611; called by muse, mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
